Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A5SP, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A5SP-01A (Primary Tumor).

[page 1 of 4]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the last page of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try printing it again.

DOB

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant Information

Location

Copied To

Report Patient Demographics (for verification purposes)

Name:

Date of Birth:

Sex: M

Adenocarcinoma, ductal
8500/3
Site: Head of pancreas
C250
9/24/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Rep

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

- A. Mesenteric nodule DV at
- B. Gallbladder at
- C. Node of importance DV at
- D. Whipple's specimen devitalized at

Clinical Information
Likely pancreatic cancer.

Diagnosis

- A. Mesenteric Nodule, Biopsy:
- Fibrous tissue, negative for malignancy.
- B. Gallbladder, Cholecystectomy:
- Chronic cholecystitis.
- C. Lymph Node (Node of Importance), Excision:
- 1 lymph node, negative for malignancy (0/1).
- D. Pancreas and Duodenum, Whipple Resection:

[page 2 of 4]
- Invasive moderately-differentiated ductal adenocarcinoma (see Synoptic Report).
- Pancreatic intraepithelial neoplasia (PanIN), grade 3/3.
- Extrapancreatic extension with perineural invasion involving groove and partial resected wall of superior mesenteric vein with positive pancreatic uncinate margin (see Comment).
- 14 lymph nodes, negative for malignancy (0/14).

Electronically signed by:

Synoptic Report
D: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:
Ductal adenocarcinoma
HISTOLOGIC GRADE:
G2: Moderately differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades peripancreatic soft tissues
Tumor invades retroperitoneal soft tissue
MARGINS:
Margin(s) involved by invasive carcinoma
Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)
LYMPH-VASCULAR INVASION:
Not identified
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis
Number examined: 15
Number involved: 0
ADDITIONAL PATHOLOGIC FINDINGS:
Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)
D: Pancreas (Exocrine), Macroscopic
SPECIMEN:
Head of pancreas
Duodenum
Gallbladder
Adjacent large vessels
Superior mesenteric vein
PROCEDURE:
Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy
TUMOR SITE:
Pancreatic head
TUMOR SIZE:
Greatest dimension: 3 cm

Gross Description

Received are specimens A to D. All requisitions and specimen containers are labelled with the patient's name The cassettes and AP identifiers are labelled with the Surgical Number

[page 3 of 4]
A. One fragment of tan tissue 0.8 x 0.3 x 0.2 cm, submitted entirely for FS. :

B. The specimen consists of a cholecystectomy specimen (9.0 x 4.5 x 2.2 cm). The overlying mesentery is unremarkable. The subhepatic roughened area is hemorrhagic, but otherwise unremarkable. Gallbladder wall measures 0.5 cm in maximum thickness and is otherwise unremarkable. The mucosa is roughened, but grossly unremarkable. The gallbladder contains some mucoid bile, but is otherwise unremarkable. Representative sections are submitted in cassette B1.

C. One lymph node, 1.3 cm in greatest dimension. Bisected and submitted entirely for FS.

D. The specimen consists of a length of stomach (4.5 x 6.0 cm in circumference), small bowel (23.0 cm in length and up to 6.5 cm in diameter), and attached pancreas and peripancreatic tissue (4.0 x 5.0 x 4.5 cm). Both the bile duct and pancreatic duct are grossly dilated. At 0.5 cm inferior to the pancreatic duct margin there is a 2.0 cm length of what appears to be a partial wall of a blood vessel within pancreatic groove. The common bile duct is patent to the ampulla. The pancreatic duct is patent only to 2.5 cm distally before it is occluded. Upon sectioning of the pancreas, there is a poorly defined fibrous white mass measuring 2.5 x 2.0 x 3.0 cm. It completely surrounds the pancreatic duct and abuts the bile duct. Grossly abuts the black painted pancreatic groove and blue painted retroperitoneal margin. The remaining surrounding soft tissue is grossly unremarkable. Representative sections are submitted as follows:

- D1. pancreatic resection margin
- D2. bile duct margin
- D3. tumor to black painted pancreatic margin and pancreatic duct
- D4. tumor to vessel in groove
- D5-6. tumor to pancreatic margin
- D7. tumor abutting bile duct and bile duct margin
- D8. tumor surrounding pancreatic tissue
- D9-10. tumor to blue painted retroperitoneal margin
- D11. normal pancreas
- D12. one lymph node bisected
- D13. two lymph nodes
- D14. one lymph node bisected
- D15. three lymph nodes
- D16. three lymph nodes
- IC/csh

Frozen Section Diagnosis

- A. Mesenteric Nodule:
- Benign fibrous tissue only.
- Negative for malignancy. Conf #
- C. Node of Importance:
- Negative for malignancy. Conf #

Reported by:

Pathologist Comment

Tumor with perineural extension is seen surrounding the partially resected superior mesenteric vein and involving the soft tissue painted margin surrounding the vein and uncinate (retroperitoneal uncinate margin positive for malignancy).

Accession
Number

Encounter

[page 4 of 4]
Number

- END OF PRINTED REPORT -

Primary Discrepancy		☒
Primary Discrepancy History		☒
Concurrent Primary/Secondary		☒

Source: NCI Genomic Data Commons file 7f065fda-7aea-4fdc-a961-7e8ebcfb5c1c (TCGA-IB-A5SP.FFEF1962-F903-4C41-A6D2-8DEF0BD35F55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).